CCDI case PBBZCE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/380852dc-c45d-4fa3-8eb9-8fbea0eef5d2

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.7 years (4,283 days).

Biospecimens (3 samples)
- Sample 0DLSWZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLSX5: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DLSYC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
